Somatic mutation profile of tumor specimen MMRF_2085_3_BM_CD138pos (aliquot MMRF_2085_3_BM_CD138pos_T1_KHS5U_L14413) from MMRF case MMRF_2085, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 74.7 years (27,278 days).
Specimen MMRF_2085_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e513eb08-7dc4-4151-801d-1faed895c540.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2085_2_PB_WBC (Blood Derived Normal), aliquot MMRF_2085_2_PB_WBC_C2_KHS5U_L11244; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fd161890-0de5-4172-933b-efb5e4bd2ce6

The open-access MAF lists 164 somatic variants for this specimen: 62 protein-altering or splice-affecting, 12 silent, 90 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 55, Missense Mutation 50, Intron 17, Silent 12, 5'UTR 9, Nonsense Mutation 6, RNA 5, 3'Flank 3, Splice Site 2, Frame Shift Del 2, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC5A1 | c.1673G>A p.R558H | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as rs201799893, CM110176, COSV56683485; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- BET1L | c.55C>G p.R19G | Missense Mutation (SNP) | VAF 62/271 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs144624940; called by muse, mutect2, varscan2
- C8G | c.61C>T p.Q21* | Nonsense Mutation (SNP) | VAF 37/116 reads (32%) | catalogued as rs1375829208; called by muse, mutect2, varscan2
- CDK17 | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774240202, COSV54131222; called by muse, mutect2, varscan2
- EIF4G3 | c.907C>T p.L303F | Missense Mutation (SNP) | VAF 59/158 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs1288974207; called by muse, mutect2, varscan2
- F2RL3 | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs757762535; called by muse, mutect2, varscan2
- FLRT2 | c.1021G>A p.G341S | Missense Mutation (SNP) | VAF 63/148 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.042); catalogued as COSV100420191; called by muse, mutect2, varscan2
- HBD | c.403G>A p.V135M | Missense Mutation (SNP) | VAF 157/303 reads (52%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.463); catalogued as COSV53081947; called by muse, mutect2, varscan2
- HDAC11 | c.859C>T p.R287W | Missense Mutation (SNP) | VAF 102/247 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs762810161, COSV99849979; called by muse, mutect2, varscan2
- HDC | c.1940C>G p.S647C | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.221); catalogued as rs1567443266; called by muse, mutect2, varscan2
- HSPD1 | c.541G>C p.E181Q | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.697); catalogued as COSV61443427, COSV61446053; called by muse, mutect2, varscan2
- IGLV2-14 | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs758257492; called by muse, varscan2
- IGLV4-69 | c.289C>T p.L97F | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377104473; called by muse, varscan2
- IGLV8-61 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.863); catalogued as rs1264522765; called by muse, mutect2, varscan2
- IL17RD | c.1729C>A p.P577T | Missense Mutation (SNP) | VAF 63/284 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.158); catalogued as rs766095716; called by muse, mutect2, varscan2
- ITGB2 | c.1832G>A p.R611H (on ENST00000302347; = p.R587H on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/191 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs772406915; called by muse, mutect2, varscan2
- OR9Q2 | c.723C>A p.C241* | Nonsense Mutation (SNP) | VAF 86/297 reads (29%) | catalogued as rs149505103, COSV61112628; called by muse, mutect2, varscan2
- PDE5A | c.1131+1G>A p.X377_splice | Splice Site (SNP) | VAF 15/50 reads (30%) | catalogued as rs763913148; called by muse, mutect2, varscan2
- PKHD1L1 | c.6567del p.K2189Nfs*27 | Frame Shift Del (DEL) | VAF 38/202 reads (19%) | catalogued as rs769716668, COSV65737892; called by mutect2, varscan2
- RFX1 | c.1168G>A p.G390S | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs761840229; called by muse, mutect2, varscan2
- SETDB1 | c.3728G>T p.R1243L | Missense Mutation (SNP) | VAF 107/567 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54977297; called by muse, mutect2, varscan2
- SLC24A3 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs960187005, COSV60114610, COSV60116312; called by muse, mutect2, varscan2
- THBS2 | c.2333A>T p.N778I | Missense Mutation (SNP) | VAF 61/86 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64677236; called by muse, mutect2, varscan2
- AC138647.1 | c.130G>T p.A44S | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- AKAP6 | c.6415C>G p.L2139V | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ARHGAP15 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.69); PolyPhen benign (0.241); called by muse, mutect2
- ATP8B2 | c.1162T>G p.Y388D (on ENST00000672630; = p.Y355D on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- ATP8B3 | c.104A>C p.Q35P | Missense Mutation (SNP) | VAF 120/285 reads (42%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- AVPR1A | c.559T>C p.F187L | Missense Mutation (SNP) | VAF 68/200 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- CDK13 | c.3879C>G p.D1293E | Missense Mutation (SNP) | VAF 59/239 reads (25%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- CILP | c.1745T>A p.M582K | Missense Mutation (SNP) | VAF 53/225 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CLCA4 | c.1889C>T p.T630I | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- COMMD4 | c.482_490del p.V161_A163del | In Frame Del (DEL) | VAF 50/148 reads (34%) | called by mutect2, pindel, varscan2
- CRACD | c.2636C>T p.A879V | Missense Mutation (SNP) | VAF 80/297 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FMNL1 | c.475T>G p.C159G | Missense Mutation (SNP) | VAF 50/206 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GJA10 | c.961G>T p.D321Y | Missense Mutation (SNP) | VAF 56/177 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- HMCN2 | c.947G>T p.R316L | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- IGLV4-69 | c.288C>G p.Y96* | Nonsense Mutation (SNP) | VAF 22/100 reads (22%) | called by muse, varscan2
- IGSF10 | c.2479A>G p.T827A | Missense Mutation (SNP) | VAF 75/432 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- IRF7 | c.829C>G p.P277A (on ENST00000397566; = p.P264A on NM_001572.5) | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- KLHL2 | c.1154A>G p.N385S | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LCE2B | c.329G>A p.C110Y | Missense Mutation (SNP) | VAF 41/179 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LDLR | c.2272G>T p.G758W | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- MALRD1 | c.5767T>A p.C1923S | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MARF1 | c.3548T>A p.L1183* | Nonsense Mutation (SNP) | VAF 41/86 reads (48%) | called by muse, mutect2, varscan2
- NFKBIA | c.493C>T p.Q165* | Nonsense Mutation (SNP) | VAF 4/10 reads (40%) | called by muse, varscan2
- NIPSNAP2 | c.712+1G>A p.X238_splice | Splice Site (SNP) | VAF 29/124 reads (23%) | called by muse, mutect2, varscan2
- PCDHA2 | c.1981G>A p.A661T | Missense Mutation (SNP) | VAF 61/261 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- PCLO | c.8436C>A p.S2812R | Missense Mutation (SNP) | VAF 82/158 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.308); called by muse, mutect2
- PRAMEF2 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- PRPS1L1 | c.634A>C p.N212H | Missense Mutation (SNP) | VAF 86/321 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRR35 | c.1262G>T p.R421L | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- RPS2 | c.177+4G>C | Splice Region (SNP) | VAF 22/53 reads (42%) | called by muse, mutect2, varscan2
- SEMA6A | c.1568del p.T524Pfs*13 | Frame Shift Del (DEL) | VAF 62/327 reads (19%) | called by mutect2, pindel, varscan2
- SIPA1L3 | c.4955G>T p.S1652I | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SMO | c.1557G>T p.K519N | Missense Mutation (SNP) | VAF 13/258 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2
- SPINK5 | c.1596T>A p.C532* | Nonsense Mutation (SNP) | VAF 48/241 reads (20%) | called by muse, mutect2, varscan2
- SPNS2 | c.1490A>G p.E497G | Missense Mutation (SNP) | VAF 73/323 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TIAM1 | c.1321G>T p.A441S | Missense Mutation (SNP) | VAF 50/185 reads (27%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WDR87 | c.2795A>G p.N932S | Missense Mutation (SNP) | VAF 48/180 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- WWC2 | c.1270C>A p.H424N | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- ZNF814 | c.1313G>C p.C438S | Missense Mutation (SNP) | VAF 52/192 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- COL9A3 | c.822G>T p.G274= | Silent (SNP) | VAF 19/76 reads (25%) | called by muse, mutect2, varscan2
- CYP4F22 | c.1065G>A p.P355= | Silent (SNP) | VAF 22/97 reads (23%) | catalogued as rs371911971, COSV99513026; called by muse, mutect2, varscan2
- DNAH1 | c.4105C>T p.L1369= | Silent (SNP) | VAF 12/64 reads (19%) | called by muse, mutect2, varscan2
- LARP6 | c.1065C>T p.H355= | Silent (SNP) | VAF 58/227 reads (26%) | catalogued as rs781281490, COSV54582762; called by muse, mutect2, varscan2
- PON3 | c.456G>A p.L152= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV99672566; called by muse, mutect2, varscan2
- PSEN1 | c.1104C>T p.I368= | Silent (SNP) | VAF 31/91 reads (34%) | catalogued as COSV56196978; called by muse, mutect2, varscan2
- PTK7 | c.2853C>T p.L951= | Silent (SNP) | VAF 9/175 reads (5%) | called by muse, mutect2
- RINL | c.1224C>T p.S408= (on ENST00000591812 / NM_001195833.2; = p.S294= on NM_198445.4) | Silent (SNP) | VAF 25/91 reads (27%) | called by muse, mutect2, varscan2
- SH2D4A | c.109C>A p.R37= | Silent (SNP) | VAF 27/109 reads (25%) | catalogued as COSV56125006; called by muse, mutect2, varscan2
- SHANK1 | c.3840G>A p.P1280= | Silent (SNP) | VAF 28/102 reads (27%) | catalogued as rs887704440; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.2121T>C p.V707= (on ENST00000540229 / NM_001371097.1; = p.V646= on NM_001009562.4) | Silent (SNP) | VAF 18/50 reads (36%) | called by muse, mutect2, varscan2
- STRN | c.531T>C p.D177= | Silent (SNP) | VAF 69/290 reads (24%) | catalogued as rs762409265; called by muse, mutect2, varscan2
- AC244197.3 | c.*3109G>T | 3'UTR (SNP) | VAF 21/72 reads (29%) | called by muse, mutect2, varscan2
- ACRP1 | n.242C>T | RNA (SNP) | VAF 27/124 reads (22%) | called by muse, mutect2, varscan2
- ADAM30 | c.-99G>C | 5'UTR (SNP) | VAF 39/174 reads (22%) | called by muse, mutect2, varscan2
- ANKRD34B | c.*744G>A | 3'UTR (SNP) | VAF 99/145 reads (68%) | called by muse, mutect2, varscan2
- ASXL2 | c.*2207C>G | 3'UTR (SNP) | VAF 26/123 reads (21%) | called by muse, mutect2, varscan2
- BAZ2A | c.2755-77A>G | Intron (SNP) | VAF 15/41 reads (37%) | called by muse, mutect2
- BLACE | n.2122C>G | RNA (SNP) | VAF 38/150 reads (25%) | called by muse, mutect2, varscan2
- BLACE | n.1247G>A | RNA (SNP) | VAF 17/83 reads (20%) | catalogued as rs1427148481; called by muse, mutect2, varscan2
- BMP6 | c.*709G>A | 3'UTR (SNP) | VAF 33/127 reads (26%) | catalogued as rs1181534453; called by muse, mutect2, varscan2
- BMP6 | c.*936_*948del | 3'UTR (DEL) | VAF 16/93 reads (17%) | called by mutect2, pindel*, varscan2
- BMP6 | c.*1196_*1211del | 3'UTR (DEL) | VAF 25/135 reads (19%) | called by mutect2, pindel*
- CACNG8 | c.*1691C>T | 3'UTR (SNP) | VAF 44/172 reads (26%) | catalogued as rs914907368; called by muse, mutect2, varscan2
- CCND2 | c.*5174T>C | 3'UTR (SNP) | VAF 28/90 reads (31%) | called by muse, mutect2, varscan2
- CCNJL | c.887+115G>C | Intron (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- CDC42BPA | c.*568A>T | 3'UTR (SNP) | VAF 40/94 reads (43%) | called by muse, mutect2, varscan2
- CDHR1 | chr10:84219316 C>A | 3'Flank (SNP) | VAF 125/467 reads (27%) | catalogued as rs972451594; called by muse, mutect2, varscan2
- CIB4 | c.187-10212G>A | Intron (SNP) | VAF 31/126 reads (25%) | catalogued as COSV56599084; called by muse, mutect2, varscan2
- CTDSPL | c.*3514G>A | 3'UTR (SNP) | VAF 82/408 reads (20%) | catalogued as rs546851935; called by muse, mutect2, varscan2
- CTNNA2 | c.*59A>C | 3'UTR (SNP) | VAF 54/108 reads (50%) | catalogued as rs1034832041; called by muse, mutect2, varscan2
- DCHS2 | n.4706A>G | RNA (SNP) | VAF 76/294 reads (26%) | called by muse, mutect2, varscan2
- DTX1 | c.-208A>G | 5'UTR (SNP) | VAF 38/125 reads (30%) | called by muse, mutect2, varscan2
- EIF4EBP3 | c.-49_-34del | 5'UTR (DEL) | VAF 49/307 reads (16%) | called by mutect2, pindel, varscan2
- FAM160A1 | c.*7706T>A | 3'UTR (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2
- FAM217B | c.*2489G>T | 3'UTR (SNP) | VAF 18/82 reads (22%) | called by muse, mutect2, varscan2
- FCGR2C | chr1:161601269 T>C | 3'Flank (SNP) | VAF 9/48 reads (19%) | called by muse, mutect2, varscan2
- FMN1 | c.*4028A>G | 3'UTR (SNP) | VAF 21/103 reads (20%) | called by muse, mutect2, varscan2
- GABRE | c.*1390del | 3'UTR (DEL) | VAF 105/173 reads (61%) | called by mutect2, pindel, varscan2
- GGA1 | c.*761G>A | 3'UTR (SNP) | VAF 49/123 reads (40%) | catalogued as rs965727653; called by muse, mutect2, varscan2
- GNA12 | c.526-29402C>T | Intron (SNP) | VAF 12/41 reads (29%) | called by muse, mutect2, varscan2
- GREM2 | c.*2715C>A | 3'UTR (SNP) | VAF 43/102 reads (42%) | called by muse, mutect2, varscan2
- GSN | c.667-151T>G | Intron (SNP) | VAF 14/54 reads (26%) | called by muse, mutect2, varscan2
- HMGA1 | c.*1213A>C | 3'UTR (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2
- HNRNPA2B1 | c.877+37G>A | Intron (SNP) | VAF 25/78 reads (32%) | called by muse, mutect2, varscan2
- HUNK | c.*4019G>T | 3'UTR (SNP) | VAF 36/105 reads (34%) | called by muse, mutect2, varscan2
- ING2 | c.172+725C>T | Intron (SNP) | VAF 5/33 reads (15%) | called by muse, mutect2, varscan2
- IPCEF1 | c.*776G>A | 3'UTR (SNP) | VAF 33/78 reads (42%) | catalogued as rs890836951; called by muse, mutect2, varscan2
- ITGAV | c.-234A>G | 5'UTR (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2, varscan2
- KAZN | c.*1575A>C | 3'UTR (SNP) | VAF 7/168 reads (4%) | called by muse, mutect2
- KCNJ3 | c.*1964del | 3'UTR (DEL) | VAF 19/67 reads (28%) | called by mutect2, pindel, varscan2
- KCNMB3 | c.-131C>T | 5'UTR (SNP) | VAF 13/101 reads (13%) | called by muse, mutect2, varscan2
- KDSR | c.*654A>G | 3'UTR (SNP) | VAF 24/88 reads (27%) | catalogued as rs1459979105; called by muse, mutect2, varscan2
- LIFR | c.*6203T>A | 3'UTR (SNP) | VAF 19/86 reads (22%) | called by muse, mutect2, varscan2
- LRRIQ3 | c.573+1811A>G | Intron (SNP) | VAF 116/329 reads (35%) | called by muse, mutect2, varscan2
- LY6K | c.*871T>A | 3'UTR (SNP) | VAF 21/64 reads (33%) | called by muse, mutect2, varscan2
- MLLT10 | c.240+18105T>C | Intron (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2, varscan2
- MMP16 | c.*3040C>A | 3'UTR (SNP) | VAF 33/116 reads (28%) | called by muse, mutect2, varscan2
- MRAS | c.*1625G>C | 3'UTR (SNP) | VAF 45/164 reads (27%) | called by muse, mutect2, varscan2
- NDUFV2 | c.*41A>C | 3'UTR (SNP) | VAF 20/65 reads (31%) | called by muse, mutect2, varscan2
- NEDD1 | c.*69A>G | 3'UTR (SNP) | VAF 72/200 reads (36%) | called by muse, mutect2, varscan2
- NEURL1B | c.*387A>T | 3'UTR (SNP) | VAF 54/232 reads (23%) | called by muse, mutect2, varscan2
- NFU1 | chr2:69437542 C>T | 5'Flank (SNP) | VAF 30/117 reads (26%) | catalogued as rs557744910; called by muse, mutect2, varscan2
- NOTCH1 | c.*804C>T | 3'UTR (SNP) | VAF 47/143 reads (33%) | catalogued as rs1190490511; called by muse, mutect2, varscan2
- PLCH1 | c.*418_*422del | 3'UTR (DEL) | VAF 13/109 reads (12%) | catalogued as rs1378050744; called by mutect2, pindel, varscan2
- PLEKHF2 | c.*1196A>G | 3'UTR (SNP) | VAF 9/45 reads (20%) | catalogued as rs924824125; called by muse, mutect2, varscan2
- POU2F2 | chr19:42088610 C>G | 3'Flank (SNP) | VAF 31/120 reads (26%) | called by muse, mutect2, varscan2
- PTCHD4 | c.908-21419T>C | Intron (SNP) | VAF 14/56 reads (25%) | called by muse, mutect2
- PTPN12 | c.2281+34G>A | Intron (SNP) | VAF 7/35 reads (20%) | called by muse, mutect2
- PYCR3 | c.*1025C>T | 3'UTR (SNP) | VAF 41/124 reads (33%) | called by muse, mutect2, varscan2
- PYCR3 | c.*1024G>A | 3'UTR (SNP) | VAF 42/123 reads (34%) | called by muse, mutect2, varscan2
- RAB2A | c.*1106C>T | 3'UTR (SNP) | VAF 34/86 reads (40%) | called by muse, mutect2, varscan2
- RAB35 | c.*1040C>T | 3'UTR (SNP) | VAF 15/40 reads (38%) | catalogued as rs940045069; called by muse, mutect2, varscan2
- RBM33 | c.*3975C>T | 3'UTR (SNP) | VAF 23/141 reads (16%) | called by muse, mutect2, varscan2
- RBM38 | c.*1392T>C | 3'UTR (SNP) | VAF 37/76 reads (49%) | called by muse, mutect2, varscan2
- RPS4XP21 | n.669C>T | RNA (SNP) | VAF 38/182 reads (21%) | catalogued as rs562456841; called by muse, mutect2, varscan2
- SCAMP4 | c.-42+24C>G | Intron (SNP) | VAF 40/159 reads (25%) | called by muse, mutect2, varscan2
- SEPTIN12 | c.374+23_374+24insA | Intron (INS) | VAF 13/35 reads (37%) | called by mutect2, pindel, varscan2
- SGSM3 | c.*97G>A | 3'UTR (SNP) | VAF 3/48 reads (6%) | catalogued as rs979452901; called by muse, mutect2
- SLC25A51P4 | n.1463+522T>C | Intron (SNP) | VAF 19/65 reads (29%) | called by muse, mutect2, varscan2
- SLC7A7 | c.*31G>A | 3'UTR (SNP) | VAF 72/183 reads (39%) | catalogued as rs929919094; called by muse, mutect2, varscan2
- SLC9A2 | c.*991A>G | 3'UTR (SNP) | VAF 34/65 reads (52%) | called by muse, mutect2, varscan2
- SLF2 | c.*2963C>T | 3'UTR (SNP) | VAF 23/116 reads (20%) | called by muse, mutect2, varscan2
- SMAD7 | c.*773G>A | 3'UTR (SNP) | VAF 40/129 reads (31%) | called by muse, mutect2, varscan2
- SOSTDC1 | c.*182A>G | 3'UTR (SNP) | VAF 52/90 reads (58%) | catalogued as rs1297208246; called by muse, mutect2, varscan2
- STK17A | c.*936T>A | 3'UTR (SNP) | VAF 13/55 reads (24%) | catalogued as rs972153653; called by mutect2, varscan2
- TANGO2 | c.*684_*685insC | 3'UTR (INS) | VAF 9/18 reads (50%) | called by mutect2*, varscan2
- TEAD3 | c.*993G>A | 3'UTR (SNP) | VAF 42/214 reads (20%) | called by muse, mutect2, varscan2
- TEX15 | c.*745_*746del | 3'UTR (DEL) | VAF 19/112 reads (17%) | catalogued as rs1404080461; called by mutect2, pindel, varscan2
- TGOLN2 | c.-247G>A | 5'UTR (SNP) | VAF 29/170 reads (17%) | catalogued as rs530474807; called by muse, mutect2, varscan2
- TM4SF4 | c.-121C>T | 5'UTR (SNP) | VAF 6/144 reads (4%) | called by muse, mutect2
- TMED9 | c.*164A>G | 3'UTR (SNP) | VAF 27/135 reads (20%) | called by muse, mutect2, varscan2
- TMEM115 | c.-353C>A | 5'UTR (SNP) | VAF 49/297 reads (16%) | called by muse, mutect2, varscan2
- TNFAIP2 | c.*1653C>G | 3'UTR (SNP) | VAF 80/184 reads (43%) | called by muse, mutect2, varscan2
- TRAPPC9 | c.*778C>T | 3'UTR (SNP) | VAF 9/34 reads (26%) | called by muse, mutect2
- TRIM24 | c.*730G>C | 3'UTR (SNP) | VAF 33/126 reads (26%) | called by muse, mutect2, varscan2
- TSPOAP1 | c.5152+180G>A | Intron (SNP) | VAF 3/14 reads (21%) | called by muse, mutect2
- UHMK1 | c.-148C>G | 5'UTR (SNP) | VAF 28/160 reads (18%) | called by muse, mutect2, varscan2
- USP7 | c.79+633G>T | Intron (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- UVRAG | c.*1284T>C | 3'UTR (SNP) | VAF 39/144 reads (27%) | catalogued as rs1368216978; called by muse, mutect2, varscan2
- XPO1 | c.2678-9G>A | Intron (SNP) | VAF 5/23 reads (22%) | called by muse, varscan2
- YWHAQ | c.*592G>A | 3'UTR (SNP) | VAF 52/231 reads (23%) | called by muse, mutect2, varscan2
